OHSU case 1921 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec46fe91-e205-48bd-987e-28b572b38bbb

Demographics
Sex at birth: male.

Diagnoses (1)
1. Myelodysplastic/myeloproliferative neoplasm, unclassifiable: ICD-O-3 morphology code: 9975/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.0 years (29,950 days); Days to last follow up: 280 days.

Biospecimens (2 samples)
- Sample 3821D: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample 3821R: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
